Gene-level copy-number profile of tumor specimen TCGA-UY-A8OD-01A from TCGA case TCGA-UY-A8OD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.3 years (24,588 days).
Specimen TCGA-UY-A8OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d7f579da-fb22-4399-af08-62832b49087a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A8OD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e72bfda-2d38-49c5-842b-1f50df7fc2e6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 28; copy number 2: 13,784; copy number 3: 14,400; copy number 4: 20,601; copy number 5: 3,708; copy number 6: 4,562; copy number 7: 407; copy number 8: 1,726; copy number 9: 143; copy number 10: 102; copy number 11: 101; copy number 12: 147; copy number 14: 11; copy number 24: 67; copy number 37: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A8OD-01A-11D-A363-01): tumor purity 0.54, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 595 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:75,479,037–77,611,834, 52 genes, copy number 10 (within-gene range 3–10): RCHY1, THAP6, ODAPH, CDKL2, G3BP2, Y_RNA, USO1, AC110615.1, RNU2-16P, PPEF2, NAAA, SDAD1, SDAD1-AS1, CXCL9, ART3, CXCL10, CXCL11, AC112719.1, NUP54, AC110795.1, SCARB2, FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13.
- chr5:50,633,124–51,275,734, 13 genes, copy number 12: AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1.
- chr7:72,558,744–73,865,890, 60 genes, copy number 12: TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2, AC211476.6, TRIM74, STAG3L3, AC211476.1, Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P, Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270.
- chr9:16,203,935–17,114,122, 11 genes, copy number 14: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1.
- chr9:35,406,755–36,022,113, 49 genes, copy number 10: ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P.
- chr9:36,072,686–36,072,762, 1 gene, copy number 10: AL138834.1.
- chr11:63,137,867–65,212,006, 119 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr11:70,398,404–71,452,868, 14 genes, copy number 9: CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1.
- chr14:21,997,539–22,509,406, 74 genes, copy number 12 (broad region; genes not listed).
- chr17:37,489,891–39,747,291, 91 genes, copy number 24–37 (broad region; genes not listed).
- chr17:52,390,515–56,511,659, 36 genes, copy number 9: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2.
- chr22:32,190,435–36,166,177, 75 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
